CGCI case BLGSP-71-21-00185 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/75d45155-1d38-4ff8-bc63-2da81a23403e

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Age at index: 76 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: primary; Age at diagnosis: 76.7 years (28,032 days); Year of diagnosis: 2014; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage I; Ann Arbor B symptoms: No; Prior malignancy: yes; Prior treatment: No; Days to last follow up: 749 days (2.1 years); Ann Arbor extranodal involvement: No; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Axillary lymph nodes.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; ECOG performance status: 0.
- Days to follow up: 749 days (2.1 years); Disease response: Tumor Free.
- Follow-up contacts recording only the day: day 673, day 674.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD3 (IHC): Negative.
- CD3: Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Ki67: Positive; Specialized molecular test: Ki-67 > 90%.
- MYC other (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Epstein-Barr Virus (ISH): Positive.
- Lactate Dehydrogenase 188 [Blood test normal range upper: 210].

Other clinical attributes
- Day 0: Weight: 75.8 kg; Height: 163 cm; BMI: 28.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-21-00185-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node(s) Axilla; Preservation method: FFPE; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Prospective.
  Slide BLGSP-71-21-00185-01-S2-HE: Section location: Bottom; Percent tumor cells: 30; Percent tumor nuclei: 75; Percent normal cells: 45; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 10.
  Slide BLGSP-71-21-00185-01-S1-HE: Section location: Top; Percent tumor cells: 35; Percent tumor nuclei: 80; Percent normal cells: 40; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 15.
- Sample BLGSP-71-21-00185-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-21-00185-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen; Days to sample procurement: 14 days; Method of sample procurement: Blood Draw; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 188; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
